Somatic mutation profile of tumor specimen TCGA-V1-A9OH-01A (aliquot TCGA-V1-A9OH-01A-11D-A41K-08) from TCGA case TCGA-V1-A9OH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9OH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b798c89-0374-4f99-941d-8f1ec27086da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9OH-10A (Blood Derived Normal), aliquot TCGA-V1-A9OH-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e000e3c-38c0-4164-9c9e-31b872470ce3

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 39, Silent 10, Frame Shift Del 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.724C>A p.L242I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100429571; called by muse, mutect2, varscan2
- ACAT2 | c.821T>G p.L274R | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100364942; called by muse, mutect2, varscan2
- AGO2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as rs1005112700, COSV99595899; called by muse, mutect2, varscan2
- APOBEC1 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs755139864, COSV99981120; called by mutect2, varscan2
- ARFGEF2 | c.2371A>G p.K791E | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100904319; called by muse, mutect2
- ARHGEF15 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100730062; called by muse, mutect2, varscan2
- AWAT1 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997212; called by mutect2, varscan2
- BACE2 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100160899; called by muse, mutect2, varscan2
- BRCA2 | c.638del p.N213Mfs*17 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs1356188847; called by mutect2, pindel, varscan2
- BUB3 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1403143522, COSV100922212; called by muse, mutect2, varscan2
- CALHM5 | c.380G>C p.C127S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100635614; called by muse, mutect2
- CCDC80 | c.1172C>A p.S391* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99244905; called by muse, mutect2, varscan2
- CCR1 | c.921G>T p.R307S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99946731; called by mutect2, varscan2
- CIP2A | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99842972; called by muse, mutect2, varscan2
- COL16A1 | c.3065T>A p.L1022Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99594748; called by muse, mutect2
- CTPS1 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV101009348; called by muse, mutect2, varscan2
- CTSG | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99361579; called by muse, mutect2, varscan2
- CWF19L2 | c.2489G>A p.G830E | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99979216; called by muse, mutect2
- CYBB | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101059778; called by muse, mutect2
- EPB41L3 | c.2828A>T p.K943I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100549505; called by muse, mutect2, varscan2
- FUT8 | c.1162G>C p.E388Q (on ENST00000360689 / NM_001371534.1; = p.E225Q on NM_004480.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.293); catalogued as COSV100651433; called by muse, mutect2, varscan2
- FXR2 | c.581T>A p.L194Q | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100007217; called by muse, mutect2
- GPSM3 | c.243G>T p.R81S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100900745; called by muse, mutect2, varscan2
- HCN1 | c.1766A>G p.D589G | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV100300830; called by muse, mutect2
- HMCN1 | c.6560A>G p.Y2187C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138702288, COSV99630748; called by muse, mutect2, varscan2
- INTS5 | c.2999G>C p.G1000A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100399678; called by muse, mutect2, varscan2
- KRT75 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV99359469; called by muse, mutect2, varscan2
- MTDH | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1476521871, COSV100292622; called by muse, mutect2, varscan2
- PCDHA7 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1554134397, COSV100971555; called by muse, mutect2, varscan2
- PRICKLE2 | c.838G>A p.E280K (on ENST00000295902; = p.E224K on NM_198859.4) | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199006668, COSV99896452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RARG | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100553537; called by muse, mutect2
- RORA | c.296G>A p.R99K (on ENST00000335670 / NM_134261.3; = p.R124K on NM_002943.3) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99832783; called by muse, varscan2
- SAMSN1 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.919); catalogued as COSV99581667; called by muse, mutect2, varscan2
- SCTR | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs764316645, COSV99191617; called by muse, mutect2, varscan2
- SEC24C | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1221516681, COSV100226942; called by muse, mutect2, varscan2
- SHANK2 | c.3385G>C p.E1129Q | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs782565293, COSV99574559, COSV99575388; called by muse, mutect2
- SLC22A7 | c.1525G>A p.A509T (on ENST00000372585 / NM_153320.2; = p.A507T on NM_006672.3) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.716); catalogued as rs777231487, COSV51483590; called by muse, mutect2, varscan2
- SLC25A6 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV101195463; called by muse, mutect2
- SNX8 | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV99770945; called by muse, mutect2, varscan2
- TAF3 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1179839592, COSV60212027; called by muse, mutect2, varscan2
- ZCWPW1 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV99546545; called by muse, mutect2, varscan2
- ALPK1 | c.2887_2918del p.G963Hfs*5 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel
- ATP10B | c.2408del p.P803Qfs*13 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- C8B | c.1372_1375del p.Y458Tfs*15 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- GLRA2 | c.344_351del p.D115Gfs*20 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- GPR32 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B4GALNT1 | c.1533C>T p.D511= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs368931577, COSV57541328; called by muse, mutect2, varscan2
- C20orf85 | c.363C>T p.C121= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100959456; called by muse, mutect2, varscan2
- DDX58 | c.2520A>G p.E840= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100008258; called by muse, mutect2
- FGB | c.354A>G p.Q118= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs1190293597, COSV100122468; called by muse, mutect2, varscan2
- IGKC | c.291C>T p.P97= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs376116848; called by muse, mutect2, varscan2
- ITGAL | c.2253G>A p.P751= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs573022300, COSV63321554; called by muse, mutect2
- MED24 | c.2145T>C p.F715= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100673241; called by muse, mutect2
- SLC25A6 | c.342G>C p.A114= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV101195464; called by muse, mutect2
- TRAV18 | c.4C>T p.L2= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- WDR20 | c.702C>T p.F234= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100085150; called by muse, mutect2, varscan2
